Somatic mutation profile of tumor specimen TCGA-55-A492-01A (aliquot TCGA-55-A492-01A-11D-A24D-08) from TCGA case TCGA-55-A492, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.4 years (25,719 days).
Specimen TCGA-55-A492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70f02542-6746-493c-bc6f-12aae8b6ea62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A492-10A (Blood Derived Normal), aliquot TCGA-55-A492-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32b9c4d4-be15-4693-9881-fcb35c781264

The open-access MAF lists 306 somatic variants for this specimen: 221 protein-altering or splice-affecting, 75 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 75, Nonsense Mutation 17, Frame Shift Del 14, RNA 5, Splice Region 4, Intron 3, Splice Site 3, Frame Shift Ins 2, 5'Flank 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- STK11 | c.169del p.E57Kfs*7 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs121913319, CD044165; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC11 | c.2744C>A p.P915Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100750968; called by muse, mutect2, varscan2
- ABCG2 | c.851G>C p.C284S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV99419628; called by muse, mutect2, varscan2
- ACAN | c.1190T>C p.V397A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.168); catalogued as COSV100718675; called by muse, mutect2, varscan2
- ACSM5 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.269); catalogued as rs371025521; called by muse, mutect2
- ADAMTS15 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs147421042; called by muse, mutect2, varscan2
- ADAMTS15 | c.2288G>T p.G763V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100143594; called by muse, mutect2, varscan2
- ADAMTS2 | c.2538C>A p.N846K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99283013; called by muse, mutect2, varscan2
- ADD2 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100036043; called by muse, mutect2, varscan2
- ADGRG4 | c.2302A>T p.T768S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99796043; called by muse, mutect2, varscan2
- AFF2 | c.168G>C p.K56N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100650563, COSV60661731, COSV60665207; called by muse, mutect2, varscan2
- AKR1B1 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99605322; called by muse, mutect2
- ALOX15B | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1353484540, COSV101205648; called by muse, mutect2, varscan2
- ANKAR | c.4094A>G p.Q1365R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.04); catalogued as COSV99854438; called by muse, mutect2, varscan2
- APAF1 | c.581G>T p.G194V (on ENST00000551964 / NM_181861.2; = p.G183V on NM_001160.3) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs1477170972, COSV100244233; called by muse, mutect2, varscan2
- APOA4 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100759275, COSV100759364, COSV63360504; called by muse, mutect2, varscan2
- ARHGAP36 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs866987298, COSV99357740; called by muse, mutect2, varscan2
- ARHGAP4 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100604122, COSV63130805; called by muse, mutect2, varscan2
- ARMC3 | c.781C>A p.L261I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV53062422; called by muse, mutect2, varscan2
- ASXL1 | c.4402G>T p.A1468S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100040169; called by muse, mutect2
- ATL2 | c.1354A>T p.I452F | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100184819; called by muse, mutect2, varscan2
- ATP6V1E2 | c.97A>C p.K33Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100120779; called by muse, mutect2, varscan2
- ATP7A | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100431229; called by muse, mutect2
- BACH2 | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100000218; called by muse, mutect2, varscan2
- BATF2 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100101825; called by muse, mutect2, varscan2
- BCORL1 | c.2548G>T p.G850W | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54401107, COSV99500145, COSV99500844; called by muse, mutect2, varscan2
- BOP1 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as COSV100266034; called by muse, mutect2, varscan2
- BTN3A2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV100709582; called by muse, mutect2, varscan2
- C3orf38 | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV59628103; called by muse, mutect2, varscan2
- CACNA2D3 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs1553736948, COSV99875077, COSV99875197; called by muse, mutect2, varscan2
- CD99 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs1205817089, COSV66991333; called by muse, mutect2
- CDH8 | c.1476C>A p.N492K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54860501, COSV54863209; called by muse, mutect2, varscan2
- CDKN2A | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100447090, COSV58727079; called by muse, varscan2
- CELA3B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1398335872, COSV61402792; called by muse, mutect2
- CEMIP | c.3284A>C p.D1095A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99586975; called by muse, mutect2, varscan2
- CENPC | c.1937T>C p.I646T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99894174; called by muse, mutect2
- CENPI | c.1875G>T p.K625N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV54500390, COSV99515587; called by muse, mutect2, varscan2
- CENPJ | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101121542; called by muse, mutect2, varscan2
- CFAP47 | c.2093G>C p.R698T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as COSV52888200, COSV52891034; called by muse, mutect2, varscan2
- CHRND | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179798517, COSV99285978; called by muse, mutect2, varscan2
- CNST | c.1048A>T p.S350C | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100830085; called by muse, mutect2
- COL24A1 | c.1708G>T p.G570C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159918621, COSV100993628; called by muse, mutect2, varscan2
- CORO7 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99227879; called by muse, mutect2
- CPED1 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100121117; called by muse, mutect2
- CRB1 | c.1463T>C p.F488S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs777377174, CM056570, COSV100957975, COSV66329081; called by muse, mutect2, varscan2
- CSMD1 | c.8298C>A p.N2766K (on ENST00000520002; = p.N2765K on NM_033225.6) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100150714; called by muse, mutect2, varscan2
- CSMD2 | c.718A>T p.I240F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV99585808, COSV99592403; called by muse, mutect2, varscan2
- CTNNA1 | c.580A>T p.R194* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100243072, COSV57074957; called by muse, mutect2, varscan2
- CTNNA3 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101050707; called by muse, mutect2, varscan2
- CTSK | c.514T>C p.S172P | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as COSV99648856; called by muse, mutect2
- CUEDC1 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.055); catalogued as COSV64227046; called by muse, mutect2
- CYP11B2 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100011213; called by muse, mutect2, varscan2
- CYP2B6 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100137635; called by muse, mutect2
- CYTH4 | c.696+1G>T p.X232_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99958044; called by muse, mutect2
- CYYR1 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100177259, COSV100177546; called by muse, mutect2, varscan2
- DAB1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100976451; called by muse, mutect2, varscan2
- DAOA | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs757009026, COSV100298829, COSV61601843; called by muse, mutect2
- DDB1 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV100074733; called by muse, varscan2
- DDR2 | c.1098A>G p.S366= | Splice Region (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100906715; called by muse, mutect2, varscan2
- DHX8 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.464); catalogued as COSV99292422; called by muse, mutect2, varscan2
- DNAJB13 | c.668del p.F223Sfs*11 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs1565179068; called by mutect2, pindel, varscan2
- DPYSL4 | c.1285G>T p.V429L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100062980; called by muse, mutect2, varscan2
- EDA2R | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV99490793; called by muse, mutect2, varscan2
- F2RL2 | c.571C>A p.R191S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99167696; called by muse, mutect2, varscan2
- FGFR4 | c.1963T>C p.W655R | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99450406; called by muse, mutect2
- FHL5 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as rs201553779, COSV100459576; called by muse, varscan2
- FITM2 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as COSV101202021; called by muse, mutect2, varscan2
- FLG | c.4411G>C p.E1471Q | Missense Mutation (SNP) | VAF 62/561 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV100911807; called by muse, mutect2, varscan2
- FOLH1 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs778134535, COSV57046475, COSV57049371; called by muse, mutect2, varscan2
- FOXN4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100142215, COSV100142226; called by muse, mutect2, varscan2
- FRMPD4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV101043402; called by muse, mutect2, varscan2
- GAB4 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV101272033; called by muse, mutect2, varscan2
- GABRA4 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.322); catalogued as COSV99974304; called by muse, mutect2, varscan2
- GABRQ | c.516del p.Y173Tfs*29 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as COSV100941240, COSV100941474, COSV64780728; called by mutect2, pindel
- GADL1 | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56981759, COSV99244698; called by muse, mutect2, varscan2
- GPR152 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100351586; called by muse, mutect2, varscan2
- GTF2H4 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV99462001; called by muse, mutect2, varscan2
- HASPIN | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99561249; called by muse, mutect2, varscan2
- HAVCR2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100324857; called by muse, mutect2
- HECW2 | c.1846C>G p.P616A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.068); catalogued as COSV53647783, COSV99647906; called by muse, mutect2, varscan2
- HEPACAM2 | c.1255G>T p.D419Y (on ENST00000394468 / NM_001039372.4; = p.D407Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100506650; called by muse, mutect2, varscan2
- HHIP | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV99667526; called by muse, mutect2, varscan2
- HS6ST3 | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941041; called by muse, mutect2, varscan2
- IFNA14 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.226); catalogued as COSV101207325; called by muse, mutect2, varscan2
- IFT122 | c.896G>T p.G299V (on ENST00000348417 / NM_052989.3; = p.G240V on NM_018262.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56200938, COSV99959562; called by muse, mutect2, varscan2
- IGKV3-11 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs751223063; called by muse, mutect2, varscan2
- IL10RB | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV99269731, COSV99270083; called by muse, varscan2
- IL13RA2 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99683222; called by muse, mutect2, varscan2
- KCNJ2 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM021623, COSV99696438; called by muse, mutect2, varscan2
- KCTD8 | c.1271A>T p.N424I | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100759778; called by muse, mutect2, varscan2
- KEAP1 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV50261803; called by muse, mutect2, varscan2
- KIF13B | c.3802C>T p.R1268C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375451644; called by muse, mutect2, varscan2
- KIF16B | c.3637G>C p.E1213Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100734650, COSV61713933; called by muse, mutect2
- KLB | c.2656T>A p.Y886N | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99962307; called by muse, mutect2, varscan2
- KRTAP3-2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101196036; called by muse, mutect2, varscan2
- KRTAP5-10 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.14); catalogued as COSV100924136, COSV100924150; called by muse, mutect2, varscan2
- L1CAM | c.3712G>A p.A1238T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs144089789, COSV100649337; called by muse, mutect2, varscan2
- LACC1 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs765113802, COSV100354708; called by muse, mutect2, varscan2
- LAMB4 | c.1694C>A p.A565E | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs751341327, COSV52727032, COSV99224836; called by muse, mutect2, varscan2
- LRP1B | c.2668C>A p.Q890K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.294); catalogued as COSV63341940; called by muse, mutect2, varscan2
- LUC7L | c.897T>G p.H299Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as COSV99551316; called by muse, mutect2, varscan2
- LYG2 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.28); catalogued as rs138652579, COSV100283718; called by muse, mutect2, varscan2
- MAD2L1 | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99633902; called by muse, mutect2, varscan2
- MAP7D2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV101107440; called by muse, mutect2, varscan2
- MAPKAPK5 | c.220A>G p.N74D | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs994196006, COSV101612898; called by muse, mutect2, varscan2
- MBD3L1 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs375438740; called by muse, mutect2, varscan2
- MED12 | c.6073C>A p.P2025T | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100378927; called by muse, mutect2, varscan2
- MEIS1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV55493233, COSV99715471; called by muse, mutect2, varscan2
- MGAT5B | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs964424143, COSV56930475, COSV56932699; called by muse, mutect2
- MGAT5B | c.1930T>A p.C644S (on ENST00000569840 / NM_001199172.2; = p.C642S on NM_144677.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100048486; called by muse, mutect2, varscan2
- MMP16 | c.1093T>A p.F365I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54163317, COSV99689337; called by muse, mutect2, varscan2
- MPDZ | c.6193A>T p.T2065S (on ENST00000319217 / NM_001330637.2; = p.T2036S on NM_003829.5) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100057156; called by muse, mutect2, varscan2
- MPRIP | c.2600A>G p.N867S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV100505978; called by muse, mutect2, varscan2
- MUC7 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100512345; called by muse, mutect2, varscan2
- MYH1 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 45/156 reads (29%) | catalogued as COSV56848488, COSV99876401; called by muse, mutect2, varscan2
- MYH8 | c.5128C>A p.L1710M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101238499; called by muse, mutect2, varscan2
- MYO18B | c.1409C>A p.A470D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100124344; called by muse, mutect2, varscan2
- NAP1L3 | c.1100A>T p.Y367F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100220519; called by muse, mutect2, varscan2
- NCKAP5 | c.4028G>A p.G1343E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV100493260; called by muse, mutect2, varscan2
- NCOA2 | c.1546C>G p.P516A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101476023; called by muse, mutect2, varscan2
- NHS | c.4650G>T p.E1550D | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV101196754; called by muse, mutect2, varscan2
- NLGN3 | c.2104C>A p.R702S (on ENST00000358741 / NM_181303.2; = p.R682S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100704877; called by muse, mutect2, varscan2
- NRIP2 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99958242; called by muse, mutect2, varscan2
- NTNG1 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs752598796, COSV99638379; called by muse, mutect2, varscan2
- OR13H1 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088332; called by muse, mutect2, varscan2
- OR14A16 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62926345; called by muse, mutect2, varscan2
- OR2L13 | c.458T>A p.I153N | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100813841; called by muse, mutect2
- OR2W3 | c.432G>T p.L144F | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831752; called by muse, mutect2, varscan2
- OR56A4 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100417619, COSV58109278; called by muse, mutect2, varscan2
- OR6K6 | c.997C>A p.H333N (on ENST00000368144; = p.H309N on NM_001005184.1) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100933759; called by muse, mutect2, varscan2
- OR8I2 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs753537479, COSV100136168; called by muse, mutect2, varscan2
- OXTR | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV100373249, COSV57478392; called by muse, mutect2, varscan2
- PAPPA2 | c.330C>A p.D110E | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as COSV100866873, COSV62786658; called by muse, mutect2, varscan2
- PCBP2 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100827679; called by muse, mutect2
- PCDHA9 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.298); catalogued as rs775532292, COSV100969815, COSV65324024; called by muse, mutect2, varscan2
- PCDHB14 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as COSV99506090; called by muse, mutect2, varscan2
- PCDHB5 | c.2224G>T p.G742W | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50648855, COSV50667357, COSV99169247; called by muse, mutect2, varscan2
- PCDHGA2 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 15/207 reads (7%) | catalogued as COSV53963775, COSV99542147, COSV99543597; called by muse, mutect2
- PCNT | c.5548G>T p.E1850* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100855716; called by muse, mutect2, varscan2
- PEX26 | c.650A>G p.Q217R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100299125; called by muse, mutect2
- PHF2 | c.2025T>A p.D675E | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100823250, COSV63680265; called by muse, mutect2, varscan2
- PLVAP | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391727756, COSV99391739; called by muse, mutect2, varscan2
- PLXNA4 | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100325568; called by muse, mutect2
- PLXNB3 | c.4198G>C p.D1400H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737647; called by muse, mutect2, varscan2
- POLA1 | c.2498G>C p.G833A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.519); catalogued as COSV100985640; called by muse, mutect2, varscan2
- POLR1G | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99185356; called by muse, mutect2
- PPM1H | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs765426741, COSV99956162; called by muse, mutect2, varscan2
- PRDM16 | c.2839G>C p.G947R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99577683; called by muse, mutect2
- PROX1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54784376; called by muse, mutect2, varscan2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, mutect2, varscan2
- RBMX | c.287del p.P96Rfs*41 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV100284557, COSV100284689; called by mutect2, varscan2
- RHBDF2 | c.2130del p.L712Sfs*205 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV99166172; called by mutect2, pindel, varscan2
- RNF17 | c.1242T>C p.S414= | Splice Region (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99693779; called by muse, mutect2, varscan2
- RRAGB | c.377G>T p.G126V (on ENST00000262850 / NM_016656.4; = p.G98V on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99469498; called by muse, mutect2, varscan2
- RTL10 | c.1021T>A p.S341T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100144253; called by muse, mutect2, varscan2
- RTL8C | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV99924352; called by muse, mutect2, varscan2
- SCN5A | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100347115, COSV100349442; called by muse, mutect2, varscan2
- SEC24D | c.2379T>G p.A793= | Splice Region (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99756422; called by muse, mutect2, varscan2
- SEMA5A | c.3007G>T p.A1003S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV101228529; called by muse, mutect2, varscan2
- SEMA6D | c.345+2T>C p.X115_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100317277; called by muse, mutect2
- SEPTIN6 | c.884A>C p.Y295S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595691; called by muse, mutect2, varscan2
- SETD1A | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99353375; called by muse, mutect2, varscan2
- SETD1A | c.4272G>T p.M1424I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99353376; called by muse, mutect2
- SI | c.3099+2T>A p.X1033_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100016326; called by muse, mutect2, varscan2
- SLA | c.719C>A p.T240N (on ENST00000338087 / NM_001045556.3; = p.T280N on NM_006748.4) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV99601975; called by muse, mutect2, varscan2
- SLC44A3 | c.1156G>T p.G386C (on ENST00000271227 / NM_001114106.3; = p.G338C on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99598402; called by muse, mutect2, varscan2
- SLCO4A1 | c.965T>C p.F322S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV99414895; called by muse, mutect2, varscan2
- SNX19 | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV99772813, COSV99773335; called by muse, mutect2, varscan2
- SORCS3 | c.3585G>T p.E1195D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.777); catalogued as COSV100865397; called by muse, mutect2, varscan2
- SPATA31D1 | c.1720C>A p.H574N | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.159); catalogued as COSV100782598, COSV99049216; called by muse, mutect2, varscan2
- SPTLC1 | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99364942; called by muse, mutect2, varscan2
- ST8SIA2 | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99184475; called by muse, mutect2, varscan2
- STX3 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276086; called by muse, mutect2, varscan2
- SULT6B1 | c.637G>T p.G213* (on ENST00000535679 / NM_001367551.1; = p.G175* on NM_001032377.2) | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99573246; called by muse, mutect2, varscan2
- SYNDIG1 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 47/174 reads (27%) | catalogued as COSV100965340; called by muse, mutect2, varscan2
- TBC1D8B | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV99344690; called by muse, mutect2
- TEX35 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.068); catalogued as COSV99274711; called by muse, mutect2, varscan2
- THOC2 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99833748; called by muse, mutect2, varscan2
- TINF2 | c.1356A>T p.*452Cext*1 | Nonstop Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as COSV99945617; called by muse, mutect2, varscan2
- TMLHE | c.896A>G p.H299R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100544931; called by muse, mutect2, varscan2
- TMPRSS15 | c.2098C>A p.H700N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV99518514; called by muse, mutect2, varscan2
- TOGARAM1 | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100753180; called by muse, mutect2, varscan2
- TOP3B | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100592626; called by muse, mutect2, varscan2
- TRMT6 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99177589; called by muse, mutect2, varscan2
- TTC8 | c.1247G>T p.W416L (on ENST00000338104 / NM_001288781.1; = p.W400L on NM_144596.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100581510; called by muse, mutect2, varscan2
- TTN | c.69571C>A p.P23191T (on ENST00000591111; = p.P15767T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | PolyPhen probably damaging (0.999); catalogued as COSV100620709; called by muse, mutect2, varscan2
- UAP1 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1159382610, COSV99617857; called by muse, mutect2, varscan2
- UBAP1 | c.1130G>T p.S377I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV99903367; called by muse, mutect2, varscan2
- UGT1A5 | c.267T>A p.F89L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100530513; called by muse, mutect2
- UGT3A1 | c.1325T>A p.V442D | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.425); catalogued as COSV99955040; called by muse, mutect2, varscan2
- VIPR1 | c.743T>C p.F248S | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100285686; called by muse, mutect2, varscan2
- VPS11 | c.218A>T p.D73V (on ENST00000620429; = p.D617V on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.355); catalogued as COSV100333863; called by muse, mutect2, varscan2
- WNT1 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs755253307, COSV99525327; called by muse, mutect2, varscan2
- XPO7 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV99381630; called by mutect2, varscan2
- YY2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs867492198, COSV100810801; called by muse, mutect2
- ZBTB18 | c.1378C>A p.H460N | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100700170; called by muse, mutect2
- ZNF365 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); catalogued as COSV101237974; called by muse, mutect2, varscan2
- ZNF449 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100203023, COSV59346763; called by muse, mutect2, varscan2
- ZNF536 | c.3647A>T p.Q1216L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.023); catalogued as COSV100835486; called by muse, mutect2, varscan2
- ZNF676 | c.835C>T p.H279Y (on ENST00000650058; = p.H247Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68093385, COSV68095615; called by muse, mutect2, varscan2
- ZNF684 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101016070; called by muse, mutect2, varscan2
- ZZZ3 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100890378; called by muse, mutect2, varscan2
- CCDC174 | c.1326dup p.D443Rfs*16 | Frame Shift Ins (INS) | VAF 7/63 reads (11%) | called by mutect2, pindel, varscan2
- CT45A1 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 59/564 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DLGAP3 | c.1039del p.A347Pfs*121 | Frame Shift Del (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- FOXO3 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- GPR148 | c.807del p.I270Sfs*5 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 47/86 reads (55%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.58T>A | Splice Region (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- IGKV3D-20 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KLHL6 | c.208_215del p.A70Rfs*38 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- LMO7 | c.713dup p.L238Ffs*12 (on ENST00000357063; = p.L253Ffs*12 on NM_005358.5) | Frame Shift Ins (INS) | VAF 77/221 reads (35%) | called by mutect2, pindel, varscan2
- LRRIQ4 | c.1034del p.L345Wfs*7 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel
- MYH9 | c.798_819del p.Q267Sfs*15 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- OGDH | c.2071del p.H691Mfs*13 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- PKD1L2 | c.427del p.D143Tfs*115 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | called by mutect2, pindel, varscan2
- RFPL4B | c.663del p.F221Lfs*39 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- SYCP2 | c.3072C>A p.N1024K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.23598del p.W7866Cfs*12 (on ENST00000367255 / NM_182961.4; = p.W7795Cfs*12 on NM_033071.3) | Frame Shift Del (DEL) | VAF 23/182 reads (13%) | called by mutect2, pindel, varscan2
- TMEM236 | c.440T>C p.L147P | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ACE | c.3726C>T p.R1242= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs372143589; called by muse, mutect2, varscan2
- ADAMTS8 | c.2669G>A p.*890= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV57299121; called by muse, mutect2, varscan2
- ADD2 | c.219G>A p.E73= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV100036047; called by muse, mutect2, varscan2
- ALDH3A1 | c.588C>T p.I196= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs113084632, COSV99855978; called by muse, mutect2, varscan2
- ALMS1 | c.4671T>A p.A1557= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV100043043; called by muse, mutect2, varscan2
- ARMC4 | c.2257C>A p.R753= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs763662864, COSV100537114, COSV59456453; called by muse, mutect2, varscan2
- ASAP2 | c.648A>G p.L216= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99856483; called by muse, mutect2
- ATP2A2 | c.912A>G p.V304= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV100428762; called by muse, mutect2, varscan2
- BCHE | c.915A>T p.A305= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100012804; called by muse, mutect2, varscan2
- BSN | c.5652G>A p.A1884= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs760305287, COSV99609084; called by muse, mutect2, varscan2
- CAPN3 | c.597G>A p.E199= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV100533196; called by muse, mutect2, varscan2
- CD5L | c.76C>T p.L26= | Silent (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- CELA3B | c.558A>G p.E186= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1296116977, COSV100448820; called by muse, mutect2
- CNTNAP5 | c.619C>T p.L207= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1389955494, COSV101443816; called by muse, mutect2, varscan2
- CSHL1 | c.663C>T p.G221= (on ENST00000309894 / NM_022581.3; = p.G127= on NM_001318.4) | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99368073; called by muse, mutect2, varscan2
- CTCFL | c.1902T>G p.P634= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99713041; called by muse, mutect2, varscan2
- CUX1 | c.2280C>A p.L760= | Silent (SNP) | VAF 10/253 reads (4%) | catalogued as COSV99472226; called by muse, mutect2
- CYP27B1 | c.1473C>A p.T491= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99874945; called by muse, mutect2, varscan2
- DAO | c.36G>A p.G12= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV57323893, COSV99948753; called by muse, mutect2, varscan2
- DNAH7 | c.3600A>T p.P1200= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100416178; called by muse, mutect2
- DOCK2 | c.975G>C p.V325= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99913782; called by muse, mutect2, varscan2
- DTX1 | c.1452T>A p.P484= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV99921938; called by muse, mutect2, varscan2
- FAM171B | c.1920T>A p.A640= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100488796; called by muse, mutect2, varscan2
- FCRL5 | c.1782C>A p.P594= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV100709096; called by muse, mutect2, varscan2
- FLNA | c.219C>T p.D73= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV61044450; called by muse, mutect2, varscan2
- FOXI2 | c.939G>T p.R313= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100511038; called by muse, mutect2
- GIGYF1 | c.2430C>T p.G810= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99309673; called by muse, mutect2
- HCAR1 | c.321G>C p.T107= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100811669; called by muse, mutect2, varscan2
- HMGCLL1 | c.930C>A p.G310= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99232679; called by muse, mutect2, varscan2
- HS3ST4 | c.1200A>G p.P400= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs371554362, COSV58824639; called by muse, mutect2, varscan2
- HS3ST6 | c.636C>T p.G212= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99562783; called by muse, mutect2, varscan2
- IGFBP3 | c.843G>A p.E281= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99298400; called by muse, mutect2, varscan2
- IQGAP2 | c.2121G>T p.R707= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99167702; called by muse, mutect2, varscan2
- ITIH6 | c.1485C>T p.P495= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99513583; called by muse, mutect2, varscan2
- LDLRAD4 | c.216C>T p.V72= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs751625190, COSV100762526; called by muse, mutect2, varscan2
- MAN2A1 | c.2016A>T p.T672= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV99811485; called by muse, mutect2, varscan2
- MAP1B | c.6474C>A p.T2158= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV57107655; called by muse, mutect2, varscan2
- MMP25 | c.1044G>A p.L348= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100339539; called by muse, mutect2, varscan2
- MYPN | c.987G>A p.A329= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs199931312; called by muse, mutect2, varscan2
- NAV3 | c.93T>C p.T31= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV99893169; called by muse, mutect2, varscan2
- NFATC1 | c.1254G>A p.Q418= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV99502119; called by muse, mutect2, varscan2
- NOBOX | c.792C>A p.P264= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99779571; called by muse, mutect2, varscan2
- NYAP2 | c.1323C>T p.S441= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99797529; called by muse, mutect2, varscan2
- OBSCN | c.12978C>T p.G4326= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99481626; called by muse, mutect2, varscan2
- OFD1 | c.2872T>C p.L958= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100366349; called by muse, mutect2, varscan2
- OGT | c.141C>A p.L47= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101035514; called by muse, mutect2, varscan2
- OR11A1 | c.918C>A p.L306= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV101010718; called by muse, mutect2, varscan2
- OR2AK2 | c.135G>T p.L45= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV63554724; called by muse, mutect2
- OR2M7 | c.90G>T p.L30= | Silent (SNP) | VAF 47/364 reads (13%) | catalogued as COSV100522612; called by muse, mutect2, varscan2
- OR4K2 | c.660T>A p.I220= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100064585; called by muse, mutect2
- PCDHB11 | c.597G>T p.A199= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs532134044, COSV99504656; called by muse, mutect2, varscan2
- PCDHGA2 | c.1893C>A p.A631= | Silent (SNP) | VAF 61/154 reads (40%) | catalogued as COSV99542148; called by muse, mutect2, varscan2
- PCMTD1 | c.543A>C p.L181= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100859741; called by muse, mutect2
- PDE3A | c.1375C>A p.R459= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100762472, COSV62973954; called by muse, mutect2, varscan2
- PKM | c.402G>T p.L134= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV100065015, COSV58787241; called by muse, mutect2, varscan2
- PLEKHG4B | c.2640G>T p.V880= (on ENST00000283426; = p.V1236= on NM_052909.5) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99360678; called by muse, mutect2, varscan2
- PML | c.1065G>T p.A355= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs769063307, COSV99167572; called by muse, mutect2, varscan2
- POM121L12 | c.216G>T p.V72= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV68693125; called by muse, mutect2, varscan2
- PRDM5 | c.186G>A p.G62= | Silent (SNP) | VAF 11/165 reads (7%) | catalogued as COSV99310959; called by muse, mutect2
- RBFOX1 | c.66T>A p.A22= | Silent (SNP) | VAF 27/269 reads (10%) | catalogued as COSV100302458; called by muse, mutect2
- RNF213 | c.759C>T p.P253= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs548738435, COSV100173693; called by muse, mutect2, varscan2
- SCN10A | c.1746C>T p.V582= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs1420634180, COSV101479465; called by mutect2, varscan2
- SLC25A43 | c.807G>A p.L269= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99474647; called by muse, mutect2, varscan2
- SLC28A3 | c.636C>A p.V212= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100883290; called by muse, mutect2, varscan2
- SLC5A10 | c.1128G>T p.A376= (on ENST00000395645 / NM_001042450.4; = p.A392= on NM_152351.5) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100525304, COSV58755352; called by muse, mutect2, varscan2
- TFAP2D | c.366C>A p.L122= | Silent (SNP) | VAF 67/165 reads (41%) | catalogued as COSV99146076; called by muse, mutect2, varscan2
- TSHZ3 | c.927C>G p.V309= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99552109; called by muse, mutect2, varscan2
- TSPOAP1 | c.3873C>T p.I1291= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV99271776; called by muse, mutect2, varscan2
- TTN | c.68523C>A p.T22841= (on ENST00000591111; = p.T15417= on NM_003319.4) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100620711; called by muse, mutect2, varscan2
- TTN | c.17043G>A p.G5681= (on ENST00000591111; = p.G4754= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100620714; called by muse, mutect2, varscan2
- TTN | c.9252T>G p.P3084= (on ENST00000591111; = p.P3038= on NM_003319.4) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100620715; called by muse, mutect2, varscan2
- TUBA3C | c.57C>A p.A19= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV101262809; called by muse, mutect2, varscan2
- TWIST1 | c.558C>T p.A186= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99643127; called by muse, mutect2, varscan2
- ZNF614 | c.1266A>T p.T422= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as COSV99571859; called by muse, varscan2
- ZNF630 | c.747C>T p.A249= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99332481; called by muse, mutect2, varscan2
- BRWD1 | c.6571+203A>T | Intron (SNP) | VAF 57/149 reads (38%) | catalogued as COSV100313717; called by muse, mutect2, varscan2
- BX119917.1 | n.54C>A | RNA (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- CHRM2 | c.-47+33791G>T | Intron (SNP) | VAF 25/106 reads (24%) | catalogued as COSV100281611; called by muse, mutect2, varscan2
- FOXP1 | c.181-17926A>T | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100561988; called by muse, mutect2, varscan2
- IGKV1-13 | n.136C>G | RNA (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- IL21R | c.-1C>A | 5'UTR (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100560304; called by muse, mutect2, varscan2
- MFRP | chr11:119344893 C>A | 5'Flank (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100793499; called by muse, mutect2, varscan2
- MIR888 | n.41C>A | RNA (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- PARGP1 | n.376A>G | RNA (SNP) | VAF 15/69 reads (22%) | catalogued as rs1464016027; called by muse, mutect2, varscan2
- SSPOP | n.3879C>T | RNA (SNP) | VAF 5/51 reads (10%) | catalogued as rs766711325, COSV100022740; called by muse, mutect2, varscan2
